Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NS, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NS-01A (Primary Tumor).

ICD-0-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0 817013
9/20/12

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6

Right lobe liver (1020 grams, 20.0 x 11.0 x 7.0 cm) and gallbladder
(10.2 x 3.7 x 1.7 cm)

DIAGNOSIS:

Liver, right lobe, hepatectomy: Grade 2 (of 4) hepatocellular carcinoma forming a mass, 11.0 x 11.0 x 10.0 cm. The surgical margin is widely free of involvement.

Gallbladder, cholecystectomy: Mild acute and chronic cholecystitis.
No stones are identified.

Photographed in lab

HiPAA Inconsistency		

Source: NCI Genomic Data Commons file 259783e1-c66f-4f83-a167-30c727805180 (TCGA-DD-A4NS.97CA96D5-990E-41F9-949D-CCCCFFB78CBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).